Somatic mutation profile of tumor specimen BA2122D (aliquot aq-BA2122D) from BEATAML1.0 case 2026, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.7 years (27,654 days).
Specimen BA2122D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28c6b2c3-41de-411b-aec5-7e076de14fba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2942D (Solid Tissue Normal), aliquot aq-BA2942D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7887602-7bfe-4928-a901-1925b9262623

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.846C>A p.C282* | Nonsense Mutation (SNP) | VAF 45/78 reads (58%) | catalogued as COSV60710380; called by mutect2, varscan2
- CFAP46 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs915496495; called by muse, mutect2
- POM121L12 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV68694674; called by muse, mutect2
- TTLL1 | c.405G>T p.W135C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56740815; called by muse, mutect2, varscan2
- CSF3R | c.2372G>A p.W791* | Nonsense Mutation (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- CSF3R | c.1023G>T p.W341C | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSSK2 | c.511C>A p.L171I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); called by muse, mutect2
- ZNF467 | c.653G>A p.C218Y | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SEMG2 | c.279G>A p.A93= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs779638348; called by mutect2, varscan2
